Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R7, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R7-01A (Primary Tumor).

cor Astrocytoma, grade II 9410013
Path Astrocytoma, gemistocytic 9411113
Site: cor Brain, Supratentorial NOS C71.0
path Brain NOS C71.9

9/29/27/13

gemistocytic differentiation
and of considerable pleomorphism
However, proliferation is below 3% and mitoses are not evident
therefore:
diffuse (gemistocytic) astrocytoma WHO grade II

Criteria	met 9/11/13
HPA Discrepancy	
Case is Grade:	DISQUALIFIED

untranslating
original reports is
housed at the
BCR.

Source: NCI Genomic Data Commons file 787cc525-6496-4ce4-93e4-1c26daca56e7 (TCGA-S9-A7R7.0C30BB62-F9E0-4702-B488-79621EA74BFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).